Somatic mutation profile of tumor specimen BA2866D (aliquot aq-BA2866D) from BEATAML1.0 case 2465, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.5 years (21,356 days).
Specimen BA2866D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b405f438-413e-4f22-9803-f982e5c7c68e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2262D (Solid Tissue Normal), aliquot aq-BA2262D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8b03a278-67ec-4230-a7df-aae30cda42a5

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGRN | c.5360C>A p.A1787D | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- LRRC75A | c.89G>T p.W30L | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- OGDHL | c.757G>T p.D253Y | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2
- SEPTIN6 | c.690+3189G>T | Intron (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2
